Somatic mutation profile of tumor specimen C3L-03963-04 (aliquot CPT0227400006) from CPTAC case C3L-03963, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 73.2 years (26,748 days).
Specimen C3L-03963-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf349ce0-6850-438f-accd-86f2fdf2e2fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03963-31 (Blood Derived Normal), aliquot CPT0227530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e31048c8-0ce5-449b-ae9d-12759033f028

The open-access MAF lists 266 somatic variants for this specimen: 172 protein-altering or splice-affecting, 52 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 52, Intron 18, Nonsense Mutation 12, Frame Shift Del 8, 5'Flank 7, 5'UTR 6, RNA 4, 3'Flank 4, 3'UTR 3, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 26/390 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 167/617 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.9811G>T p.E3271* | Nonsense Mutation (SNP) | VAF 11/125 reads (9%) | catalogued as COSV101446869; called by muse, mutect2
- ADAMTS1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV99536119; called by muse, mutect2, varscan2
- ANKS1B | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV61372778; called by muse, mutect2, varscan2
- APBB2 | c.1265G>A p.R422H (on ENST00000295974 / NM_001166050.2; = p.R423H on NM_004307.2) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1170607832; called by muse, mutect2, varscan2
- ATP11A | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 23/389 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52109089; called by muse, mutect2
- BCAM | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54305152; called by muse, mutect2, varscan2
- BSN | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99609848; called by muse, mutect2
- BTBD6 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771518146; called by muse, mutect2, varscan2
- CELF5 | c.1105A>T p.M369L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs773264011; called by muse, mutect2, varscan2
- COL5A3 | c.1843C>A p.R615S | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV53406593; called by muse, mutect2, varscan2
- CYP24A1 | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 85/562 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383090763; called by muse, mutect2, varscan2
- ERICH1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.314); catalogued as rs760410692, COSV50640291; called by muse, mutect2
- FBXW7 | c.1514del p.R505Pfs*19 (on ENST00000281708 / NM_001349798.2; = p.R425Pfs*19 on NM_018315.5) | Frame Shift Del (DEL) | VAF 30/210 reads (14%) | catalogued as COSV55901126, COSV55908371, COSV55911517; called by mutect2, pindel*, varscan2
- FER1L6 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67552147; called by muse, mutect2
- GNA14 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758196305, COSV59028817; called by muse, mutect2, varscan2
- GPSM1 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.738); catalogued as rs782759946, COSV61305290, COSV61306022; called by muse, mutect2, varscan2
- HCN1 | c.2585C>A p.P862Q | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.368); catalogued as rs751073592; called by muse, mutect2, varscan2
- KCNQ2 | c.806G>A p.W269* | Nonsense Mutation (SNP) | VAF 48/688 reads (7%) | catalogued as rs796052633; called by muse, mutect2
- MFSD11 | c.1212C>G p.F404L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV100333573, COSV60622291, COSV60624897; called by muse, mutect2, varscan2
- MUC16 | c.15002G>A p.G5001E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.07); catalogued as rs762666779; called by muse, mutect2, varscan2
- MYEF2 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs144897007; called by muse, mutect2, varscan2
- MYH7 | c.3172G>T p.D1058Y | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880770; ClinVar: uncertain significance; called by muse, mutect2
- NISCH | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV61898424; called by muse, mutect2, varscan2
- NSD3 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100388966; called by muse, mutect2
- OR4D11 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs764386306, COSV57584438; called by muse, mutect2
- OR4M1 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 28/444 reads (6%) | catalogued as rs772553895; called by muse, mutect2
- OTULIN | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs762088767; called by muse, mutect2, varscan2
- PCDH8 | c.1682T>C p.I561T | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100131956; called by muse, mutect2, varscan2
- PCYOX1L | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs146403308; called by muse, mutect2, varscan2
- PDE4DIP | c.4051A>G p.I1351V | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs781855882; called by muse, mutect2, varscan2
- PIK3C3 | c.2540G>T p.R847L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100010537; called by muse, mutect2, varscan2
- PRB3 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99685506; called by muse, varscan2
- RBM4 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV100029660; called by muse, mutect2
- RILPL1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs754132549; called by muse, mutect2, varscan2
- RIMS1 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53470837; called by muse, mutect2
- SDAD1 | c.1380A>G p.I460M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs148330502; called by muse, mutect2, varscan2
- SEC14L4 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as rs762499785, COSV55399658; called by muse, mutect2, varscan2
- SERPINB4 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV61985552; called by muse, mutect2, varscan2
- SOCS6 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs1178246578; called by muse, mutect2, varscan2
- SPHKAP | c.4231C>G p.P1411A | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749391388; called by muse, mutect2, varscan2
- SULF2 | c.1424A>G p.H475R | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as rs368203432; called by muse, mutect2, varscan2
- TBC1D4 | c.2852C>T p.S951F | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66491934; called by muse, mutect2, varscan2
- TBX5 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV59864878; called by muse, mutect2, varscan2
- TEP1 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV52997714; called by muse, mutect2
- UHRF2 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99436572; called by muse, mutect2
- UNC5D | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs528277879, COSV99775720; called by muse, mutect2, varscan2
- XPO5 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1561875398, COSV54832201; called by muse, mutect2
- ZBTB20 | c.1600G>C p.G534R (on ENST00000474710 / NM_001164342.2; = p.G461R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV61861547, COSV61866513; called by muse, mutect2, varscan2
- ZDHHC11 | c.825C>G p.N275K | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV52073380; called by muse, mutect2
- ZFHX4 | c.7097T>C p.V2366A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs748771946; called by muse, mutect2, varscan2
- ZFP36L2 | c.508T>G p.Y170D | Missense Mutation (SNP) | VAF 54/944 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99144281; called by muse, mutect2
- ZNF479 | c.439del p.Q147Nfs*54 | Frame Shift Del (DEL) | VAF 24/240 reads (10%) | catalogued as COSV100482659; called by mutect2, varscan2
- ZNF675 | c.1417A>C p.I473L | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1423130743; called by muse, mutect2
- ZNF727 | c.1170C>G p.H390Q | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV70701717; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12770G>T p.R4257I | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ACOX1 | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 116/488 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADARB2 | c.1721A>T p.H574L | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADGRG7 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- ADRB3 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 60/1374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGR2 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.17456A>C p.K5819T | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ANKS6 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- ARHGAP33 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ARNTL2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.334); called by muse, mutect2
- ATP9A | c.2059A>T p.T687S | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- BOP1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.773); called by muse, mutect2
- C19orf57 | c.1736del p.P579Lfs*40 (on ENST00000586783 / NM_001345843.1; = p.P579Lfs*12 on NM_024323.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/225 reads (19%) | called by mutect2, pindel, varscan2
- CCDC7 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- CCNB3 | c.3494T>C p.V1165A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CD5 | c.776G>A p.S259N | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CD58 | c.639A>C p.R213S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- CDC16 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- CDC20B | c.1143A>G p.I381M | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- CNTNAP2 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- CNTNAP5 | c.1838C>A p.P613Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A1 | c.2602G>C p.A868P | Missense Mutation (SNP) | VAF 60/458 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- COL5A1 | c.4294G>T p.G1432W | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.9770A>T p.Y3257F (on ENST00000297405 / NM_001363185.1; = p.Y3088F on NM_052900.3) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUX2 | c.4265C>A p.P1422Q | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- CYP3A5 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DBNL | c.250T>G p.W84G | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DBX2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DDX60L | c.4048A>T p.I1350L | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DIRAS1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2
- DYDC1 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSCB | c.379A>C p.K127Q | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GLYAT | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPATCH2L | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- GPR155 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPR179 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GRAP | c.580del p.H194Tfs*69 | Frame Shift Del (DEL) | VAF 42/165 reads (25%) | called by mutect2, pindel, varscan2
- GRM7 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- GSS | c.32A>C p.D11A | Missense Mutation (SNP) | VAF 118/673 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.216); called by mutect2, varscan2
- HTRA3 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- IFNA21 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- IFT122 | c.1852-7C>A | Splice Region (SNP) | VAF 42/404 reads (10%) | called by muse, mutect2, varscan2
- IGF2R | c.792C>A p.Y264* | Nonsense Mutation (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- IL26 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ITGAX | c.1556del p.G519Vfs*7 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | called by mutect2, pindel
- KCNC1 | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0586 | c.597A>T p.L199F (on ENST00000619416 / NM_001244190.2; = p.L214F on NM_014749.5) | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF4B | c.2857A>G p.S953G | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- KLHL42 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.143); called by muse, mutect2
- KREMEN2 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- L3MBTL3 | c.1574C>G p.P525R | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC15 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.04); called by muse, mutect2
- MACF1 | c.8876C>T p.S2959L | Missense Mutation (SNP) | VAF 42/205 reads (20%) | called by muse, mutect2, varscan2
- MAP3K5 | c.813C>A p.Y271* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | called by mutect2, varscan2
- MEIOC | c.887G>C p.C296S | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MMP16 | c.1583A>C p.D528A | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- MTRF1L | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MUC17 | c.8674A>G p.T2892A | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MUC19 | n.5950G>T | Splice Region (SNP) | VAF 27/254 reads (11%) | called by muse, mutect2, varscan2
- MYCBP2 | c.5057G>T p.S1686I (on ENST00000357337; = p.S1724I on NM_015057.5) | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- MYO16 | c.2612A>G p.Q871R | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- MYO18B | c.6116T>A p.V2039E | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2
- NELL1 | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NEU1 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 65/593 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NIPBL | c.5605A>G p.I1869V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NLRP9 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR14J1 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2
- OR2AG1 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4Q2 | c.599T>A p.V200E | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- OR9G4 | c.306T>A p.F102L | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); called by muse, mutect2
- PEG3 | c.4240G>T p.E1414* | Nonsense Mutation (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- PKD1L1 | c.7955T>A p.V2652E | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- RALGAPA2 | c.4385T>A p.I1462N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RBBP8 | c.2183T>G p.F728C | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- REG3A | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF13 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RNF152 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNPC3 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2
- RPH3AL | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 96/414 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTN4RL2 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SCN7A | c.1192del p.E398Kfs*39 | Frame Shift Del (DEL) | VAF 23/211 reads (11%) | called by mutect2, pindel, varscan2
- SETBP1 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SIDT1 | c.345-1G>T p.X115_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- SLC17A8 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SLC2A7 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 80/336 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SMARCA1 | c.1948G>C p.G650R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX18 | c.432C>G p.Y144* | Nonsense Mutation (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2
- SNX22 | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); called by muse, mutect2
- SP5 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 88/647 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SRL | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ST7 | c.1043A>G p.Y348C (on ENST00000265437 / NM_021908.3; = p.Y325C on NM_018412.4) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUOX | c.1571C>A p.P524Q | Missense Mutation (SNP) | VAF 54/361 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SV2B | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2
- TAS2R31 | c.884G>C p.R295P | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); called by muse, mutect2
- TDRD10 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- TMEM151A | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- TRAV8-7 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- TTN | c.93469A>T p.S31157C (on ENST00000591111; = p.S23733C on NM_003319.4) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | PolyPhen benign (0.163); called by muse, mutect2, varscan2
- UPF2 | c.2337G>T p.L779F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP13 | c.2298C>A p.S766R | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- VPS54 | c.1594G>C p.V532L | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- WNK3 | c.1228G>C p.G410R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- YEATS2 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- YTHDC2 | c.1799A>C p.D600A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2
- YTHDF3 | c.1510A>C p.K504Q | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZC3HAV1 | c.2500G>C p.D834H | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZEB1 | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZFX | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF460 | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF479 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF521 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF529 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.045); called by muse, mutect2
- ZNF543 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 63/317 reads (20%) | called by muse, mutect2, varscan2
- ZNF804B | c.3916del p.S1306Lfs*5 | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | called by mutect2, pindel, varscan2
- ZNF852 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ACACB | c.2355G>A p.A785= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as rs1489830732; called by muse, mutect2
- ACTBL2 | c.201C>A p.T67= | Silent (SNP) | VAF 31/297 reads (10%) | catalogued as COSV101379433; called by muse, mutect2, varscan2
- ADAP1 | c.480G>A p.L160= | Silent (SNP) | VAF 39/266 reads (15%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5709C>T p.L1903= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56368812; called by muse, mutect2
- ANKRD12 | c.2268G>A p.K756= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- ARMH4 | c.1971C>G p.T657= | Silent (SNP) | VAF 33/438 reads (8%) | catalogued as COSV50776605; called by muse, mutect2
- BDKRB2 | c.1002C>T p.I334= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs138780728, COSV60017496; called by muse, mutect2, varscan2
- BPNT2 | c.804T>C p.G268= | Silent (SNP) | VAF 23/390 reads (6%) | catalogued as rs1266682890; called by muse, mutect2
- CDH10 | c.1161C>G p.S387= | Silent (SNP) | VAF 44/228 reads (19%) | catalogued as COSV52581700; called by muse, mutect2, varscan2
- CHKB | c.321A>G p.G107= | Silent (SNP) | VAF 29/362 reads (8%) | called by muse, mutect2
- CSRNP3 | c.672G>T p.T224= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV58777849; called by muse, mutect2
- DLGAP2 | c.2835G>A p.L945= | Silent (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- ECEL1 | c.141G>A p.G47= | Silent (SNP) | VAF 57/233 reads (24%) | catalogued as rs1249462399; called by muse, mutect2, varscan2
- EFCAB1 | c.27G>T p.L9= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2
- EFCAB12 | c.834G>A p.R278= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1893C>T p.S631= | Silent (SNP) | VAF 50/431 reads (12%) | catalogued as rs142447348; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- FAT3 | c.6810A>G p.E2270= | Silent (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- FAXC | c.96C>A p.S32= | Silent (SNP) | VAF 129/540 reads (24%) | called by muse, mutect2, varscan2
- FGA | c.2298G>T p.L766= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as rs776549090; called by muse, mutect2, varscan2
- GDF6 | c.612G>T p.P204= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as rs777541984; called by muse, mutect2, varscan2
- GHR | c.1155A>C p.G385= | Silent (SNP) | VAF 67/227 reads (30%) | called by muse, mutect2, varscan2
- GPRIN1 | c.1890A>C p.A630= | Silent (SNP) | VAF 23/330 reads (7%) | catalogued as rs146821721; called by muse, mutect2
- HDAC4 | c.1189C>T p.L397= | Silent (SNP) | VAF 36/410 reads (9%) | called by muse, mutect2
- HFM1 | c.781T>C p.L261= | Silent (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- IFFO1 | c.1077A>G p.P359= (on ENST00000396840 / NM_001330324.2; = p.P362= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2
- KRTAP19-1 | c.141C>A p.G47= | Silent (SNP) | VAF 37/543 reads (7%) | catalogued as COSV66861511; called by muse, mutect2
- L3MBTL1 | c.1428T>C p.Y476= (on ENST00000418998 / NM_001377303.1; = p.Y386= on NM_015478.7) | Silent (SNP) | VAF 27/213 reads (13%) | catalogued as rs201640833, COSV64228768; called by muse, mutect2, varscan2
- LGR5 | c.1977C>A p.A659= | Silent (SNP) | VAF 61/395 reads (15%) | called by muse, mutect2, varscan2
- LMF2 | c.949C>T p.L317= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as rs1031456849; called by muse, mutect2
- LRRC3 | c.81G>T p.L27= | Silent (SNP) | VAF 18/229 reads (8%) | called by muse, mutect2
- LYAR | c.894A>T p.P298= | Silent (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- MC5R | c.555C>T p.Y185= | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as rs143944533; called by muse, mutect2
- MKRN3 | c.1071C>A p.I357= | Silent (SNP) | VAF 23/284 reads (8%) | catalogued as COSV58810443; called by muse, mutect2
- NDST3 | c.1990T>C p.L664= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs1383931002; called by mutect2, varscan2
- NLRC4 | c.1677C>T p.I559= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as rs746517877, COSV61593614; called by muse, mutect2
- NOTCH1 | c.5277G>A p.K1759= | Silent (SNP) | VAF 28/299 reads (9%) | catalogued as rs565412257; called by muse, mutect2, varscan2
- OR2AJ1 | c.402T>A p.I134= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- OR52R1 | c.6G>T p.V2= | Silent (SNP) | VAF 27/213 reads (13%) | catalogued as COSV100617635; called by muse, mutect2, varscan2
- PLOD3 | c.1182C>T p.D394= | Silent (SNP) | VAF 18/320 reads (6%) | catalogued as rs761178372; called by muse, mutect2
- PYGB | c.1581T>C p.S527= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- RAB38 | c.384A>G p.K128= | Silent (SNP) | VAF 42/203 reads (21%) | called by muse, mutect2, varscan2
- RBP4 | c.18G>C p.A6= | Silent (SNP) | VAF 41/586 reads (7%) | called by muse, mutect2
- SMC1B | c.2244T>C p.C748= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- SNTB1 | c.597C>T p.P199= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- SORCS2 | c.990C>T p.S330= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs187216479; called by muse, mutect2
- TAC3 | c.285C>T p.V95= | Silent (SNP) | VAF 78/546 reads (14%) | catalogued as rs1400257304; called by muse, mutect2, varscan2
- TET3 | c.2271C>A p.I757= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- TMEM201 | c.22C>T p.L8= | Silent (SNP) | VAF 17/302 reads (6%) | catalogued as rs1349756798; called by muse, mutect2
- VN1R2 | c.393G>C p.L131= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- WWC2 | c.2763C>T p.S921= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as rs1236029270; called by muse, mutect2, varscan2
- ZDHHC11B | c.825C>G p.T275= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7098G>T p.V2366= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874221 T>C | 5'Flank (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- AGTR1 | c.-20A>T | 5'UTR (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2
- APOBEC2 | chr6:41052340 T>C | 5'Flank (SNP) | VAF 38/207 reads (18%) | catalogued as rs1192460843; called by muse, mutect2, varscan2
- AREG | c.*143del | 3'UTR (DEL) | VAF 22/176 reads (13%) | called by mutect2, pindel
- ASB10 | chr7:151187412 C>A | 5'Flank (SNP) | VAF 27/200 reads (14%) | called by muse, varscan2
- ATM | c.3994-39A>G | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs778072373; called by muse, mutect2
- ATP6AP2 | c.-96G>A | 5'UTR (SNP) | VAF 105/359 reads (29%) | called by muse, mutect2, varscan2
- B3GAT3 | chr11:62621988 G>A | 5'Flank (SNP) | VAF 38/318 reads (12%) | catalogued as rs1480139308; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1475A>C | 3'UTR (SNP) | VAF 30/243 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700390 C>T | 3'Flank (SNP) | VAF 149/682 reads (22%) | catalogued as rs1338408097; called by muse, mutect2, varscan2
- C3 | c.2583+46A>T | Intron (SNP) | VAF 60/581 reads (10%) | called by muse, mutect2, varscan2
- CADM1 | c.-21A>C | 5'UTR (SNP) | VAF 42/452 reads (9%) | called by muse, mutect2
- DYNLT1 | c.272-92A>T | Intron (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- ELF4 | c.-25G>T | 5'UTR (SNP) | VAF 61/235 reads (26%) | catalogued as rs749504954, COSV57453192; called by muse, mutect2, varscan2
- FOLH1B | n.1665T>A | RNA (SNP) | VAF 19/225 reads (8%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.280C>A | RNA (SNP) | VAF 22/375 reads (6%) | called by muse, mutect2
- GDAP1L1 | c.374-201C>T | Intron (SNP) | VAF 35/311 reads (11%) | catalogued as rs756673923; called by muse, mutect2, varscan2
- GPR89A | c.-15T>G | 5'UTR (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- HLCS | c.1451+14A>C | Intron (SNP) | VAF 77/388 reads (20%) | called by muse, mutect2, varscan2
- IDH3B | c.*11T>G | 3'UTR (SNP) | VAF 67/414 reads (16%) | called by muse, mutect2, varscan2
- IGSF22 | c.2096-1276A>G | Intron (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- IMP4 | c.112+97T>G | Intron (SNP) | VAF 22/359 reads (6%) | called by muse, mutect2
- KCP | chr7:128877006 C>G | 3'Flank (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- MYSM1 | chr1:58700068 C>G | 5'Flank (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- NDUFV1 | c.72+190C>A | Intron (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- OPN3 | c.374-11307G>T | Intron (SNP) | VAF 14/289 reads (5%) | called by muse, mutect2
- OPRM1 | c.1164+1907T>C | Intron (SNP) | VAF 47/283 reads (17%) | catalogued as rs1165808835; called by muse, mutect2, varscan2
- OXSM | chr3:25789908 T>A | 5'Flank (SNP) | VAF 14/165 reads (8%) | called by muse, mutect2
- PARVB | c.712+28A>G | Intron (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- QRFPR | c.562-1555C>T | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- SCN5A | c.612-156A>G | Intron (SNP) | VAF 14/93 reads (15%) | catalogued as rs1458122299; called by muse, mutect2, varscan2
- SLC29A1 | c.-303G>T | 5'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1130-50C>T | Intron (SNP) | VAF 55/517 reads (11%) | called by muse, mutect2, varscan2
- STRA6 | c.-16+1101C>T | Intron (SNP) | VAF 19/268 reads (7%) | catalogued as rs1346054788; called by muse, mutect2
- SYCE1 | chr10:133554718 G>T | 3'Flank (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- SYCE1 | chr10:133554720 G>T | 3'Flank (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
- TCFL5 | c.1381-3761C>T | Intron (SNP) | VAF 28/216 reads (13%) | catalogued as rs748564747; called by muse, mutect2, varscan2
- TTN | c.10361-5102C>T | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1486628659; called by muse, mutect2
- UBTFL2 | n.365C>T | RNA (SNP) | VAF 45/637 reads (7%) | called by muse, mutect2
- UBTFL2 | n.204C>A | RNA (SNP) | VAF 26/145 reads (18%) | catalogued as rs774304092; called by muse, mutect2, varscan2
- WNK4 | c.3432-17C>T | Intron (SNP) | VAF 32/462 reads (7%) | called by muse, mutect2
- WT1 | chr11:32435789 C>T | 5'Flank (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
